Gene-level copy-number profile of tumor specimen TARGET-20-PAEEYP-09A from TARGET case TARGET-20-PAEEYP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (567 days).
Specimen TARGET-20-PAEEYP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.dccacf63-aba1-5d59-b6f3-2e010ff063ae.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PAEEYP-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 351 have no estimate.
https://portal.gdc.cancer.gov/files/d794dfc7-0e47-4057-9055-e9231bde7f6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 539; copy number 1: 496; copy number 2: 59,115; copy number 3: 122.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:144,364,364–144,579,434, 9 genes (within-gene range 0–2): ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412.
- chr3:18,345,377–18,445,588, 2 genes (within-gene range 0–2): SATB1, AC144521.1.
- chr3:152,243,828–152,465,780, 4 genes: MBNL1, MBNL1-AS1, TMEM14EP, Y_RNA.
- chr5:180,967,189–181,006,727, 4 genes (within-gene range 0–2): AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 496. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
